TCGA case TCGA-SR-A6MV — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: Tufts Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/66af140d-deab-440f-bb58-b8c3da2c3ca5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (2)
1. Paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8680/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 35.8 years (13,074 days); Year of diagnosis: 2004; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,682 days (10.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 415 days (1.1 years); Days to treatment end: 418 days (1.1 years); Treatment dose: 129 mCi; Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Carcinoid tumor, NOS: ICD-O-3 morphology code: 8240/3; Tissue or organ of origin: Duodenum; Classification of tumor: Synchronous primary; Age at diagnosis: 35.8 years (13,084 days); Days to diagnosis: 10 days.
   Treatment given: Treatment type: Whipple; Days to treatment start: 0 days; Treatment anatomic sites: Pancreas.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 3,269 days (9.0 years); Disease response: With Tumor.
- Days to follow up: 3,682 days (10.1 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Other.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SR-A6MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-SR-A6MV-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-SR-A6MV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-SR-A6MV-10C, TCGA-SR-A6MV-10D (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Retroperitoneum; Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Paraganglioma; Disease detected on screening: No; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Carcinoid (neuroendocrine tumor).
- Other malignancy form, Surgery: Other malignancy surgery type: Whipple resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,682 days; disease-specific survival: no event (censored), 3,682 days; progression-free interval: no event (censored), 3,682 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SR-A6MV-01A-11D-A35H-01): tumor purity 0.65, ploidy 3.74, whole-genome doublings 1.
